CCDI case PBCLSS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/3e3dbdce-11e3-4903-bb83-bc7626b8defb

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Intra-abdominal lymph nodes; Age at diagnosis: 2.8 years (1,034 days).

Biospecimens (2 samples)
- Sample 0DUYNU: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DUYNX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
